Somatic mutation profile of tumor specimen MMRF_2526_1_BM_CD138pos (aliquot MMRF_2526_1_BM_CD138pos_T1_KHS5U_L13276) from MMRF case MMRF_2526, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.5 years (25,377 days).
Specimen MMRF_2526_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b799551-8570-4c00-9748-58321c9217e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2526_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2526_1_PB_WBC_C3_KHS5U_L13275; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e3cc59c-dc9d-48e5-9a7c-f2569c4624c4

The open-access MAF lists 115 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 31, Intron 16, Silent 10, 5'UTR 5, 5'Flank 2, RNA 2, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A1 | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52877945; called by muse, mutect2, varscan2
- CDH26 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs536661438, COSV54849684; called by muse, mutect2, varscan2
- COL1A1 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144820445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV56694009; called by muse, mutect2, varscan2
- CSMD3 | c.4455T>G p.I1485M (on ENST00000297405 / NM_001363185.1; = p.I1381M on NM_052900.3) | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.703); catalogued as COSV104398027; called by muse, mutect2, varscan2
- DHX9 | c.1494A>C p.L498F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62358699; called by muse, mutect2
- GK2 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.842); catalogued as COSV62626618; called by muse, mutect2, varscan2
- IGHV2-5 | c.315C>A p.N105K | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs373003751; called by muse, mutect2
- LRRC19 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as COSV101195786; called by muse, mutect2, varscan2
- NKX2-6 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1400414265; called by muse, mutect2, varscan2
- NLRP14 | c.2438del p.P813Qfs*5 | Frame Shift Del (DEL) | VAF 65/238 reads (27%) | catalogued as COSV55068887; called by mutect2, pindel, varscan2
- NUP43 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs756524726; called by muse, mutect2, varscan2
- OR5D18 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 34/477 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100450668, COSV61737650; called by muse, mutect2
- PCSK5 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65084226; called by muse, mutect2, varscan2
- POGLUT2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs148677512; called by muse, mutect2, varscan2
- SEMA7A | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs373206524; called by muse, mutect2, varscan2
- TRMT1 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1268591790; called by muse, mutect2, varscan2
- ZBBX | c.745T>A p.C249S | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100284963; called by muse, mutect2, varscan2
- ZFP42 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV58818377; called by muse, mutect2, varscan2
- ABCA1 | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ABHD10 | c.886_897del p.D296_D299del | In Frame Del (DEL) | VAF 63/175 reads (36%) | called by mutect2, pindel, varscan2
- AHNAK | c.17305T>C p.S5769P | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATG16L2 | c.644+1G>A p.X215_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- AUTS2 | c.2866A>T p.S956C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- C2CD5 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CASKIN2 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CCL20 | c.57C>A p.H19Q | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCNB3 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- DERPC | c.988A>C p.N330H | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF3A | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPB41 | c.2387G>A p.S796N (on ENST00000343067 / NM_001166005.2; = p.S587N on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/139 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- HTR1D | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHG1 | c.11_33del p.K4Sfs*88 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- KCNQ2 | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KIF17 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 96/118 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2B | c.7717T>A p.S2573T | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KPNA3 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 118/144 reads (82%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NCOR1 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PPP1R12A | c.2569T>C p.F857L | Missense Mutation (SNP) | VAF 115/301 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SBNO1 | c.361A>G p.T121A (on ENST00000420886; = p.T120A on NM_018183.5) | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNN | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SPATA31D1 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- STARD8 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVEP1 | c.4193G>C p.C1398S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYN1 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTC34 | c.2516G>A p.G839D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.011); called by muse, mutect2
- UBE2NL | c.417A>C p.E139D | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP47 | c.2729C>A p.S910* (on ENST00000399455 / NM_001372095.1; = p.S822* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- ADRA2B | c.270G>T p.A90= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as rs1339259089, COSV101337363, COSV69787250; called by muse, mutect2, varscan2
- AMPD3 | c.2013G>A p.T671= (on ENST00000396553 / NM_001025389.2; = p.T680= on NM_000480.3) | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs781091901; called by muse, mutect2, varscan2
- CNTRL | c.1944A>G p.T648= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs771052869; called by muse, mutect2, varscan2
- ICAM4 | c.711G>A p.A237= | Silent (SNP) | VAF 23/208 reads (11%) | catalogued as rs758114506; called by muse, mutect2, varscan2
- KCNH2 | c.1338C>T p.G446= | Silent (SNP) | VAF 97/254 reads (38%) | called by muse, mutect2, varscan2
- MYT1 | c.2445C>T p.Y815= | Silent (SNP) | VAF 45/366 reads (12%) | catalogued as rs752932508; called by muse, mutect2, varscan2
- NR1D2 | c.129T>G p.S43= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- OR52E4 | c.237T>G p.T79= | Silent (SNP) | VAF 45/238 reads (19%) | called by muse, mutect2, varscan2
- OSGEP | c.537C>T p.N179= | Silent (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- ZNF507 | c.2301T>C p.S767= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- ABLIM1 | chr10:114434652 G>A | 3'Flank (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- AC103993.1 | n.1231A>C | RNA (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- ACP1 | chr2:264914 G>T | 5'Flank (SNP) | VAF 43/90 reads (48%) | catalogued as rs769828590, COSV55246067; called by muse, mutect2, varscan2
- ADGRA3 | c.1810-689T>A | Intron (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2
- AQP12A | chr2:240688993 T>G | 5'Flank (SNP) | VAF 104/261 reads (40%) | called by muse, mutect2, varscan2
- BMP5 | c.-479A>T | 5'UTR (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.-174G>C | 5'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- CERK | c.*2699G>A | 3'UTR (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- CHRM3 | c.*5985A>T | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- DCX | c.*367A>G | 3'UTR (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- EBAG9 | c.429+767C>T | Intron (SNP) | VAF 13/203 reads (6%) | called by muse, mutect2
- FAM133A | c.*629C>G | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, varscan2
- FAM133A | c.*704T>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, varscan2
- FST | c.*1088T>A | 3'UTR (SNP) | VAF 6/9 reads (67%) | catalogued as rs1038454994; called by muse, mutect2, varscan2
- GART | c.1298+279del | Intron (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- GART | c.1298+273T>C | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- GATAD2A | c.*2926T>C | 3'UTR (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- GDA | c.*2269C>T | 3'UTR (SNP) | VAF 35/126 reads (28%) | catalogued as rs1008640468; called by muse, mutect2, varscan2
- GPR173 | c.*1105G>T | 3'UTR (SNP) | VAF 76/198 reads (38%) | catalogued as rs1362280227; called by muse, mutect2, varscan2
- GPR173 | c.*2096C>T | 3'UTR (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- GPX4 | c.85-299C>T | Intron (SNP) | VAF 80/171 reads (47%) | called by muse, mutect2, varscan2
- HCAR2 | c.*333T>C | 3'UTR (SNP) | VAF 185/490 reads (38%) | called by muse, mutect2, varscan2
- IQCJ | c.*261C>A | 3'UTR (SNP) | VAF 80/194 reads (41%) | called by muse, mutect2, varscan2
- KNTC1 | c.6150-255A>T | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, varscan2
- KRT33A | c.-2C>A | 5'UTR (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2, varscan2
- KRT78 | c.*798T>A | 3'UTR (SNP) | VAF 70/196 reads (36%) | called by muse, mutect2, varscan2
- NDOR1 | c.1065+21G>A | Intron (SNP) | VAF 127/276 reads (46%) | called by muse, mutect2, varscan2
- NNT | c.*462del | 3'UTR (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- NR2F2 | c.*168A>G | 3'UTR (SNP) | VAF 24/75 reads (32%) | catalogued as rs1164933471; called by muse, mutect2, varscan2
- NSD1 | c.*2010G>C | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- PAX4 | c.*491C>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs926523639, COSV58388107; called by muse, mutect2, varscan2
- PCBP2 | c.1061+3389A>G | Intron (SNP) | VAF 246/553 reads (44%) | catalogued as rs1007196234; called by muse, mutect2, varscan2
- PCDH18 | c.*1755A>C | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- PDXDC1 | c.22-8885C>A | Intron (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- PDXDC1 | c.22-8884A>C | Intron (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- POU5F1B | c.*3102dup | 3'UTR (INS) | VAF 27/50 reads (54%) | called by mutect2, pindel, varscan2
- PTPRC | c.100+1841A>G | Intron (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- PWWP3B | c.*418T>G | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- RAB22A | c.*6148G>A | 3'UTR (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- RBM7 | c.-114C>T | 5'UTR (SNP) | VAF 38/84 reads (45%) | catalogued as rs1384139076; called by muse, mutect2, varscan2
- REPS2 | c.*4765C>A | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- RNF32 | c.684+1595C>A | Intron (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- SLC16A7 | c.*209A>C | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- SLC36A4 | c.*1180G>T | 3'UTR (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- SLC6A6 | c.*1514T>A | 3'UTR (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- SLC9A8 | c.*562G>A | 3'UTR (SNP) | VAF 102/232 reads (44%) | called by muse, mutect2, varscan2
- SMPD4 | c.*535G>T | 3'UTR (SNP) | VAF 170/473 reads (36%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6452G>A | Intron (SNP) | VAF 40/86 reads (47%) | catalogued as rs942560366; called by muse, mutect2, varscan2
- SPATA31D5P | n.190C>T | RNA (SNP) | VAF 58/136 reads (43%) | called by muse, mutect2, varscan2
- TACR3 | c.*1680G>C | 3'UTR (SNP) | VAF 22/56 reads (39%) | catalogued as rs923771201, COSV59200976; called by muse, varscan2
- THEM4 | c.287-156A>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV64296017; called by muse, mutect2
- THRA | c.1110+1002C>T | Intron (SNP) | VAF 62/230 reads (27%) | catalogued as rs1055766532; called by muse, mutect2, varscan2
- TRMT5 | c.*2661G>A | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs1445883249; called by muse, mutect2, varscan2
- UBXN2A | c.*1585T>G | 3'UTR (SNP) | VAF 57/149 reads (38%) | called by muse, mutect2, varscan2
- UTP25 | c.2027+171T>C | Intron (SNP) | VAF 38/61 reads (62%) | called by muse, mutect2, varscan2
- VAMP1 | c.*41T>G | 3'UTR (SNP) | VAF 113/276 reads (41%) | called by muse, mutect2, varscan2
- VPS26B | c.-64G>A | 5'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
